TCGA case TCGA-YR-A95A — Cholangiocarcinoma (TCGA-CHOL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/779ce92d-1abd-44fc-9021-eda4d7f08fff

Demographics
Sex at birth: male; Race: white; Country of residence at enrollment: Brazil; Age at index: 52 years; Vital status: Dead; Days to death: 26 days.

Diagnoses (2)
1. Cholangiocarcinoma (the primary disease): ICD-O-3 morphology code: 8160/3; ICD-10 code: C24.0; Tissue or organ of origin: Extrahepatic bile duct; Site of resection or biopsy: Biliary tract, NOS; Classification of tumor: primary; Age at diagnosis: 52.8 years (19,292 days); Year of diagnosis: 2009; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: NX; AJCC pathologic M: M1; AJCC pathologic stage: Stage IV; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1.
   Pathology details: Consistent pathology review: Yes; Perineural invasion present: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Subsequent primary of the adrenal gland (histology not recorded by GDC). Age at diagnosis: 52.9 years (19,309 days); Days to diagnosis: 17 days; Prior treatment: Yes.
   Recorded as not given: Ablation or Embolization, NOS, for initial diagnosis; Organ Transplantation to Liver, for initial diagnosis; Pharmaceutical Therapy, NOS, for initial diagnosis; Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (1 entry)
- Days to follow up: 26 days; Disease response: With Tumor.

Molecular and laboratory tests
- CA19-9: 18.15 U/mL; Blood test normal range lower: 0; Blood test normal range upper: 39.
- Total Bilirubin 2 mg/dL.
- Prothrombin time (INR, as labelled on the TCGA clinical form) 0.9 [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 1.38 ng/mL [Blood test normal range lower: 0; Blood test normal range upper: 15].
- Creatinine 0.8 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.2].
- Albumin 4.3 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.4; Blood test normal range upper: 4.8].
- Platelets 240000 (unit not recorded by GDC) [Blood test normal range lower: 125000; Blood test normal range upper: 450000].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 77 kg; Height: 177 cm; BMI: 24.6.

Family history
- Relative with cancer history: yes; Relationship type: Sister; Relationship primary diagnosis: Brain Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-YR-A95A-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 130 mg.
  Slide TCGA-YR-A95A-01A-01-TSA: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 60; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-YR-A95A-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-YR-A95A-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; New tumor event diagnosis indicator: Yes.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Primary pathology: Submitted tumor site: Bile duct; Histologic diagnosis: Cholangiocarcinoma, hilar/perihilar; Definitive surgical procedure: Segmentectomy, Multiple.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: Adrenal gland; New tumor event liver transplant: No; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; New tumor event ablation embolization treatment: No.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 26 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 26 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 17 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-YR-A95A-01A-12D-A416-01): tumor purity 0.75, ploidy 1.85, whole-genome doublings 0.
